Somatic mutation profile of tumor specimen 0DIKK0 from CCDI case PBBSXN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Alveolar soft part sarcoma; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 5.4 years (1,960 days).
Specimen 0DIKK0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93e2b1ef-e01f-4a4c-95e9-29f0f0f38b1d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIKJD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c7c2753-4635-4c1c-93b8-5ad204f5f4fa

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Nonsense Mutation 1, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DPP10 | c.1404T>A p.C468* | Nonsense Mutation (SNP) | VAF 32/1198 reads (3%) | called by muse, mutect2
- FSIP2 | c.3384C>T p.H1128= | Silent (SNP) | VAF 40/1741 reads (2%) | called by muse, mutect2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 6/99 reads (6%) | called by muse, mutect2
